Somatic mutation profile of tumor specimen TCGA-O2-A5IB-01A (aliquot TCGA-O2-A5IB-01A-11D-A27K-08) from TCGA case TCGA-O2-A5IB, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage III; Age at diagnosis: 71.8 years (26,211 days).
Specimen TCGA-O2-A5IB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0761d34b-c57a-4976-beb9-aaca8c88021d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-O2-A5IB-10A (Blood Derived Normal), aliquot TCGA-O2-A5IB-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59ec16a2-be19-461f-8bd4-11ec0e8a54fb

The open-access MAF lists 289 somatic variants for this specimen: 214 protein-altering or splice-affecting, 66 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 66, Splice Site 12, Nonsense Mutation 12, Frame Shift Del 8, RNA 3, Splice Region 2, Translation Start Site 2, Frame Shift Ins 2, Intron 2, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2489+1G>C p.X830_splice | Splice Site (SNP) | VAF 15/19 reads (79%) | hotspot (GDC flag); catalogued as rs764754259, CS030560, CS030561, CS133197, COSV57295644, COSV57300119, COSV57302985; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1559T>C p.I520T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV99288905; called by muse, mutect2, varscan2
- ABCD1 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV99497737; called by muse, mutect2, varscan2
- ADAMTS13 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1554790056, COSV100747142; called by muse, mutect2, varscan2
- ADAMTS20 | c.2836G>T p.D946Y | Missense Mutation (SNP) | VAF 63/103 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101166335, COSV67140803; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2194C>A p.H732N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV99719806; called by muse, mutect2, varscan2
- ADGRG4 | c.18A>G p.I6M | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.024); catalogued as rs769706208, COSV99795973; called by muse, mutect2, varscan2
- AMBN | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.163); catalogued as COSV100534401; called by muse, mutect2, varscan2
- AMER1 | c.1029C>A p.S343R | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100366646; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3223A>G p.I1075V | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs914633525, COSV99783784; called by muse, mutect2, varscan2
- ANKRD12 | c.5687C>A p.S1896* | Nonsense Mutation (SNP) | VAF 62/91 reads (68%) | catalogued as COSV100041618; called by muse, mutect2, varscan2
- ANKRD45 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 169/216 reads (78%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100322564; called by muse, mutect2, varscan2
- AP002512.3 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); catalogued as COSV100392573, COSV56565836; called by muse, mutect2, varscan2
- ASCC3 | c.5072G>T p.G1691V | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775383834, COSV100976405, COSV64977410; called by muse, mutect2, varscan2
- ASXL1 | c.1718G>C p.R573P | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV100040062; called by muse, mutect2, varscan2
- ASXL3 | c.5516C>T p.T1839I | Missense Mutation (SNP) | VAF 28/597 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs765369686, COSV99325550; called by muse, mutect2
- ATG9B | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV52486767, COSV52494057, COSV99871877; called by muse, mutect2, varscan2
- ATP2B3 | c.1413C>A p.C471* | Nonsense Mutation (SNP) | VAF 200/286 reads (70%) | catalogued as COSV99685070; called by muse, mutect2, varscan2
- ATP7A | c.2512G>T p.D838Y | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100431204; called by muse, mutect2, varscan2
- BCAN | c.2461C>A p.L821M | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100228264; called by muse, varscan2
- BCOR | c.3466C>A p.P1156T | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV100653546; called by muse, mutect2, varscan2
- BLMH | c.946A>C p.I316L | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.127); catalogued as COSV99913175; called by muse, mutect2, varscan2
- BTN2A2 | c.1502G>C p.G501A | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV100760499; called by muse, mutect2, varscan2
- C2CD5 | c.2359-1G>T p.X787_splice | Splice Site (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100448875; called by muse, mutect2, varscan2
- CACNA1G | c.878del p.G293Afs*71 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | catalogued as COSV61739478; called by mutect2, pindel
- CAMSAP2 | c.2293A>T p.R765W (on ENST00000236925 / NM_001297707.2; = p.R754W on NM_203459.3) | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99373664; called by muse, mutect2, varscan2
- CAMSAP2 | c.4319G>T p.G1440V (on ENST00000236925 / NM_001297707.2; = p.G1429V on NM_203459.3) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99373669; called by muse, mutect2, varscan2
- CASZ1 | c.3040G>T p.G1014C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100681722; called by muse, mutect2, varscan2
- CBY2 | c.136A>T p.I46F | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV100137676; called by muse, mutect2, varscan2
- CDC7 | c.1099C>A p.R367S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.281); catalogued as COSV99319827; called by muse, mutect2, varscan2
- CDH22 | c.1877C>G p.A626G | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV100952927; called by muse, mutect2, varscan2
- CFAP47 | c.2818G>T p.A940S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV52883872, COSV52892724, COSV99935401; called by muse, mutect2, varscan2
- CHIT1 | c.1074G>C p.W358C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99705427; called by muse, mutect2, varscan2
- CLASP2 | c.4496A>G p.Q1499R (on ENST00000359576; = p.Q1498R on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as COSV100223783; called by muse, mutect2, varscan2
- CNTN1 | c.983A>T p.Q328L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV100751601; called by muse, mutect2, varscan2
- CNTN5 | c.3124A>G p.I1042V | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs1437050864, COSV99678744; called by muse, mutect2, varscan2
- COL4A5 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100088487; called by muse, mutect2, varscan2
- CR1 | c.4586A>T p.D1529V | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.967); catalogued as COSV100887790; called by muse, mutect2, varscan2
- CRISPLD1 | c.661G>C p.G221R | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100082194; called by muse, mutect2, varscan2
- CRYBG2 | c.4783G>T p.G1595C | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100366789; called by muse, mutect2, varscan2
- CSMD1 | c.8902T>A p.S2968T (on ENST00000520002; = p.S2967T on NM_033225.6) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.985); catalogued as COSV100150375; called by muse, mutect2, varscan2
- CYB5R4 | c.1511+1G>A p.X504_splice | Splice Site (SNP) | VAF 14/75 reads (19%) | catalogued as COSV100859718; called by muse, mutect2, varscan2
- CYHR1 | c.96A>G p.A32= | Splice Region (SNP) | VAF 58/111 reads (52%) | catalogued as COSV100023885; called by muse, mutect2, varscan2
- DACH2 | c.772+1G>T p.X258_splice | Splice Site (SNP) | VAF 23/47 reads (49%) | catalogued as rs747496266, COSV100913522; called by muse, mutect2, varscan2
- DDX11 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99299896; called by muse, mutect2
- DDX25 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759109195, COSV99699856, COSV99700013; called by muse, mutect2, varscan2
- DEFB112 | c.90T>A p.S30R | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs1012164398, COSV100452168; called by muse, mutect2, varscan2
- DISP3 | c.1042A>G p.R348G | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV99609223; called by muse, mutect2, varscan2
- DLC1 | c.3457T>C p.Y1153H (on ENST00000276297 / NM_001348081.2; = p.Y716H on NM_006094.5) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99360306; called by muse, mutect2, varscan2
- DLC1 | c.2338G>T p.D780Y (on ENST00000276297 / NM_001348081.2; = p.D343Y on NM_006094.5) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52300754; called by muse, mutect2, varscan2
- DLD | c.269C>A p.A90D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99227295; called by muse, mutect2, varscan2
- DMD | c.8378C>T p.S2793F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100628149; called by muse, mutect2, varscan2
- DOCK4 | c.1683G>T p.K561N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV101447903, COSV70237603; called by muse, mutect2, varscan2
- EPB41 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 135/228 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1431488367, COSV100548987; called by muse, mutect2, varscan2
- EPHA4 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV56045399, COSV99917002; called by muse, mutect2, varscan2
- ESX1 | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1051511075, COSV101006481; called by muse, mutect2, varscan2
- EXOC2 | c.661+1G>T p.X221_splice | Splice Site (SNP) | VAF 33/84 reads (39%) | catalogued as COSV100033859; called by muse, mutect2, varscan2
- F5 | c.3985A>T p.T1329S | Missense Mutation (SNP) | VAF 118/828 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV100889166; called by muse, varscan2
- FAAH2 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100887373, COSV66504753; called by muse, mutect2, varscan2
- FAM184A | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs781343964, COSV100138025; called by muse, varscan2
- FAM24A | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 131/166 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100925085; called by muse, mutect2, varscan2
- FAM47C | c.1168C>A p.L390I | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV100792773; called by muse, mutect2, varscan2
- FAT3 | c.7637T>G p.I2546R | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99967676; called by muse, varscan2
- FBN2 | c.2608C>A p.L870I | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as COSV99328780; called by muse, mutect2, varscan2
- FBXO40 | c.1832T>A p.L611* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as COSV100573229; called by muse, mutect2, varscan2
- FBXO9 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99762533; called by muse, mutect2, varscan2
- FCGR2B | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 17/180 reads (9%) | catalogued as rs10917661, CM078107, COSV52683600; called by muse, mutect2
- FCN2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/11 reads (91%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99391352, COSV99391451; called by muse, mutect2
- FCRL2 | c.300A>G p.I100M | Missense Mutation (SNP) | VAF 150/199 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100829950; called by muse, mutect2, varscan2
- FNDC7 | c.1160G>T p.R387I | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV99601409; called by muse, mutect2, varscan2
- FOXRED1 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99702893; called by muse, mutect2, varscan2
- FSTL5 | c.808T>C p.C270R | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100057801; called by muse, mutect2, varscan2
- GABRR3 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs373783184; called by muse, varscan2
- GATA1 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV100936822; called by muse, mutect2, varscan2
- GDNF | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100427497; called by muse, mutect2, varscan2
- GIGYF1 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV99309647; called by muse, mutect2, varscan2
- GPR107 | c.1072A>C p.I358L | Missense Mutation (SNP) | VAF 62/87 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV100714699; called by muse, mutect2, varscan2
- GPR173 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.838); catalogued as COSV100212334; called by muse, mutect2, varscan2
- GPR75 | c.362T>A p.F121Y | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100766233; called by muse, mutect2
- GRIN1 | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100160478; called by muse, mutect2
- GRIN3A | c.2336G>T p.G779V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100701632, COSV62453805; called by muse, mutect2
- HBG2 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV100400660; called by muse, mutect2, varscan2
- HDAC6 | c.3104C>T p.S1035L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs781873237, COSV100491006; called by muse, mutect2, varscan2
- HECTD3 | c.131C>G p.P44R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV55799936, COSV99870299; called by muse, mutect2
- HJV | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100382342; called by muse, mutect2, varscan2
- HLX | c.1456G>T p.G486C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); catalogued as COSV100854573; called by muse, mutect2, varscan2
- HMGA2 | c.114A>T p.E38D | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as COSV100666584; called by muse, mutect2, varscan2
- HNRNPCL1 | c.267A>T p.K89N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV58611594; called by muse, mutect2, varscan2
- HUS1B | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.975); catalogued as COSV100033861; called by muse, mutect2, varscan2
- IL18RAP | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as COSV51826411; called by muse, mutect2, varscan2
- IRF1 | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs755784838, COSV99810606; called by muse, mutect2
- IRS1 | c.1183A>T p.S395C | Missense Mutation (SNP) | VAF 76/82 reads (93%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.751); catalogued as COSV100524718; called by muse, mutect2, varscan2
- ITPR1 | c.3167A>G p.H1056R (on ENST00000354582; = p.H1041R on NM_002222.7) | Missense Mutation (SNP) | VAF 92/116 reads (79%) | SIFT tolerated (0.15); PolyPhen benign (0.322); catalogued as COSV100232114; called by muse, mutect2, varscan2
- JAG2 | c.3616G>T p.G1206C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV100078586; called by muse, mutect2, varscan2
- KAT6B | c.1002A>G p.I334M | Missense Mutation (SNP) | VAF 88/100 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99768456; called by muse, mutect2, varscan2
- KCNA4 | c.398A>G p.E133G | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as COSV100069084; called by muse, mutect2, varscan2
- KCTD19 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100431066; called by muse, mutect2, varscan2
- KIAA1210 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.278); catalogued as COSV101274289; called by muse, mutect2
- KIF17 | c.1938G>A p.Q646= | Splice Region (SNP) | VAF 78/268 reads (29%) | catalogued as COSV99929316; called by muse, mutect2, varscan2
- KLC4 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV99432208; called by muse, mutect2, varscan2
- LRFN1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.019); catalogued as rs1412354288, COSV99953095; called by muse, mutect2, varscan2
- LRRC8B | c.397G>C p.A133P | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100446622; called by muse, mutect2, varscan2
- MAGEA6 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV100262881, COSV61449035; called by muse, mutect2, varscan2
- MAGEB2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100975709; called by muse, mutect2, varscan2
- MAGEC2 | c.617G>T p.C206F | Missense Mutation (SNP) | VAF 228/334 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV55998003, COSV99909733; called by muse, mutect2, varscan2
- MDH1B | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs770263229, COSV100982224; called by muse, mutect2, varscan2
- MDM1 | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100291943; called by muse, mutect2, varscan2
- MED28 | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV99403789; called by muse, mutect2, varscan2
- MMP11 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV99303266; called by muse, mutect2, varscan2
- MOCOS | c.1202T>C p.I401T | Missense Mutation (SNP) | VAF 173/241 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1555651772, COSV99733616; called by muse, mutect2, varscan2
- MTM1 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100080554; called by muse, mutect2, varscan2
- MTTP | c.707A>G p.H236R | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1285947070, COSV99645351; called by muse, mutect2, varscan2
- MYO3B | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1170286692, COSV100510778; called by muse, mutect2, varscan2
- NDST2 | c.388A>T p.N130Y | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100014109, COSV55215576; called by muse, mutect2, varscan2
- NF1 | c.7550G>T p.R2517L (on ENST00000358273 / NM_001042492.3; = p.R2496L on NM_000267.3) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.393); catalogued as COSV100647570; called by muse, mutect2, varscan2
- NFKB1 | c.1557C>G p.Y519* (on ENST00000394820 / NM_001382627.1; = p.Y520* on NM_003998.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 40/88 reads (45%) | catalogued as COSV99897476; called by muse, mutect2, varscan2
- NID2 | c.2402-1G>T p.X801_splice | Splice Site (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99356838; called by muse, mutect2, varscan2
- NLRP14 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100205196; called by muse, mutect2, varscan2
- NOTCH4 | c.584T>A p.V195D | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV100900788; called by muse, mutect2, varscan2
- NTNG1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142686945; called by muse, mutect2, varscan2
- OR2L13 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100813831; called by muse, mutect2, varscan2
- OR2M2 | c.376A>T p.I126F | Missense Mutation (SNP) | VAF 152/324 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100677257; called by muse, mutect2, varscan2
- OR2M2 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100677258; called by muse, mutect2, varscan2
- OR2T34 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100170425; called by muse, mutect2, varscan2
- OR4K5 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100262442; called by muse, mutect2, varscan2
- OR5H1 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as COSV100641736, COSV63403082; called by muse, mutect2, varscan2
- PAQR6 | c.622T>C p.W208R (on ENST00000292291 / NM_001272108.2; = p.W102R on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99431333; called by muse, mutect2
- PCDHA2 | c.1079C>A p.S360* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100974013, COSV65367286; called by muse, mutect2, varscan2
- PCNX3 | c.4063A>T p.T1355S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100856515; called by muse, mutect2, varscan2
- PCYT2 | c.170A>G p.H57R | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100155613; called by muse, mutect2, varscan2
- PFAS | c.1918-1G>A p.X640_splice | Splice Site (SNP) | VAF 37/47 reads (79%) | catalogued as COSV100119015; called by muse, mutect2, varscan2
- PHEX | c.1110G>T p.M370I | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1306355598, COSV101039789; called by muse, mutect2, varscan2
- PKHD1 | c.2791C>A p.P931T | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100583674; called by muse, mutect2, varscan2
- PLEKHH2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.87); PolyPhen benign (0.026); catalogued as COSV99174892; called by muse, mutect2, varscan2
- PLEKHH3 | c.491-1G>C p.X164_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99512143; called by muse, mutect2
- PLG | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as rs775335671, COSV99804865; called by muse, mutect2, varscan2
- POLM | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 52/63 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV99641911; called by muse, mutect2, varscan2
- POTEE | c.431A>T p.H144L | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100388355; called by mutect2, varscan2
- POTEF | c.431A>T p.H144L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100665076; called by muse, mutect2, varscan2
- POU2F1 | c.1776G>T p.M592I (on ENST00000541643 / NM_001365848.1; = p.M615I on NM_002697.4) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV99611470; called by muse, mutect2, varscan2
- POU2F1 | c.1777G>T p.A593S (on ENST00000541643 / NM_001365848.1; = p.A616S on NM_002697.4) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99611474; called by muse, mutect2, varscan2
- PPP6R3 | c.1872G>C p.E624D (on ENST00000393800 / NM_001352375.2; = p.E544D on NM_018312.5) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV99676859; called by muse, mutect2, varscan2
- PTH2 | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.006); catalogued as COSV99569600; called by muse, mutect2, varscan2
- PTPRD | c.2748A>T p.E916D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100645521; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1098G>A p.W366* | Nonsense Mutation (SNP) | VAF 61/142 reads (43%) | catalogued as COSV99770215; called by muse, mutect2, varscan2
- RASGEF1C | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.631); catalogued as rs1306927795, COSV100746112; called by muse, mutect2, varscan2
- RASL11B | c.94C>G p.R32G | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99954499; called by muse, mutect2, varscan2
- RIT2 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1182646862, COSV99950581; called by muse, mutect2, varscan2
- RPGR | c.1415-1G>T p.X472_splice | Splice Site (SNP) | VAF 21/50 reads (42%) | catalogued as rs868377988, COSV100140175; called by muse, mutect2
- RPGR | c.1415-2A>T p.X472_splice | Splice Site (SNP) | VAF 21/50 reads (42%) | catalogued as COSV100140178; called by muse, mutect2
- RPS6KA2 | c.1979G>T p.R660L | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99691455, COSV99692255; called by muse, mutect2, varscan2
- RSPH6A | c.1489C>G p.L497V | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV99679937; called by muse, mutect2, varscan2
- SBF1 | c.2471G>T p.G824V | Missense Mutation (SNP) | VAF 57/66 reads (86%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.731); catalogued as COSV100817888; called by muse, mutect2, varscan2
- SCN7A | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV101313286; called by muse, mutect2, varscan2
- SCN8A | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100634014; called by muse, varscan2
- SLC35E1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.446); catalogued as rs565590794, COSV101290782; called by muse, mutect2, varscan2
- SLC35F3 | c.170C>A p.S57* | Nonsense Mutation (SNP) | VAF 49/128 reads (38%) | catalogued as COSV100785424, COSV100785461; called by muse, mutect2
- SLC35F4 | c.838G>T p.A280S (on ENST00000339762 / NM_001352015.2; = p.A244S on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100334011, COSV100334393; called by muse, mutect2, varscan2
- SLC44A2 | c.1878G>T p.R626S | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV100213310; called by muse, mutect2, varscan2
- SLC6A4 | c.1574T>A p.V525E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99911469; called by muse, mutect2, varscan2
- SLC6A7 | c.968C>A p.T323N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100046410; called by muse, mutect2, varscan2
- SLIT3 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as COSV100268626; called by muse, mutect2, varscan2
- SPRTN | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99149899; called by muse, mutect2, varscan2
- STAC2 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100336434; called by muse, mutect2, varscan2
- SYT4 | c.1260C>A p.H420Q | Missense Mutation (SNP) | VAF 447/650 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54900451, COSV54902612; called by muse, mutect2, varscan2
- SYT4 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 150/198 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs1339842154, COSV54899242; called by muse, mutect2, varscan2
- TACR1 | c.941T>A p.L314Q | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV100538001; called by muse, mutect2, varscan2
- TAGAP | c.829T>G p.F277V | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100487525; called by muse, mutect2, varscan2
- TBPL2 | c.528C>A p.D176E | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99905455; called by muse, mutect2, varscan2
- TBX3 | c.390-1G>A p.X130_splice | Splice Site (SNP) | VAF 40/108 reads (37%) | catalogued as COSV99983924; called by muse, mutect2, varscan2
- TCEAL3 | c.113T>A p.V38E | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54580187, COSV99685242; called by muse, mutect2, varscan2
- TENM1 | c.4634A>T p.Y1545F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100950387; called by muse, mutect2, varscan2
- TGIF2LX | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.062); catalogued as COSV99383443; called by muse, mutect2, varscan2
- THOC2 | c.16G>C p.V6L | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99833705; called by muse, mutect2, varscan2
- TMEM132D | c.1967T>A p.I656N | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV101242950; called by muse, mutect2, varscan2
- TMEM200A | c.1453G>A p.G485R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99759562; called by muse, mutect2, varscan2
- TMEM244 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV100933595; called by muse, mutect2
- TMEM51 | c.155A>T p.E52V | Missense Mutation (SNP) | VAF 92/347 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV101051552; called by muse, mutect2, varscan2
- TNF | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as COSV101403216; called by muse, mutect2, varscan2
- TNN | c.2103C>A p.D701E | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV99512371; called by muse, mutect2, varscan2
- TROAP | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 71/83 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV99226914; called by muse, mutect2, varscan2
- TTC17 | c.2447A>G p.D816G | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.057); catalogued as COSV99235562; called by muse, mutect2, varscan2
- TTC7B | c.2273C>A p.A758D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100128164; called by muse, mutect2, varscan2
- TTL | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1380480903, COSV99271404; called by muse, mutect2, varscan2
- TULP4 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs371686812; called by muse, mutect2, varscan2
- UBC | c.130A>T p.I44F | Missense Mutation (SNP) | VAF 124/256 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV100299046; called by muse, mutect2, varscan2
- UBE2NL | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 178/248 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1300587994; called by muse, mutect2, varscan2
- UCK2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 19/26 reads (73%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.083); catalogued as COSV100903010; called by muse, mutect2, varscan2
- UGT3A1 | c.915C>A p.N305K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV99954984; called by muse, mutect2, varscan2
- WDR44 | c.2000C>A p.S667Y | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561716; called by muse, mutect2, varscan2
- WWC3 | c.3082C>T p.Q1028* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | catalogued as COSV101081578; called by muse, mutect2, varscan2
- YY2 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV100810798; called by muse, mutect2, varscan2
- ZC3H7B | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 77/179 reads (43%) | catalogued as rs772584301, COSV100687507; called by muse, mutect2, varscan2
- ZNF233 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100492346; called by muse, mutect2, varscan2
- ZNF385D | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs752571574, COSV55752607; called by muse, mutect2, varscan2
- ZNF407 | c.1592C>G p.T531R | Missense Mutation (SNP) | VAF 105/440 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as rs757565072, COSV99996139; called by muse, mutect2, varscan2
- ZNF454 | c.508G>T p.G170* | Nonsense Mutation (SNP) | VAF 23/33 reads (70%) | catalogued as COSV100195107; called by muse, mutect2, varscan2
- ZNF804B | c.1029A>T p.K343N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.518); catalogued as COSV100304636; called by muse, mutect2, varscan2
- ZNF91 | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100323063; called by muse, mutect2, varscan2
- ZSWIM5 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100655633; called by muse, mutect2, varscan2
- DISP1 | c.90dup p.C31Lfs*2 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- DST | c.13332_13339dup p.T4447Mfs*2 (on ENST00000361203 / NM_001374722.1; = p.T2035Mfs*2 on NM_015548.5) | Nonsense Mutation (INS) | VAF 18/64 reads (28%) | called by mutect2, varscan2
- FLII | c.2097_2107del p.P700Gfs*9 | Frame Shift Del (DEL) | VAF 59/192 reads (31%) | called by mutect2, pindel, varscan2
- IGKV1-16 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 107/233 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- INPPL1 | c.2666del p.I889Tfs*69 | Frame Shift Del (DEL) | VAF 20/35 reads (57%) | called by mutect2, pindel, varscan2
- ITPR3 | c.541del p.D181Tfs*3 | Frame Shift Del (DEL) | VAF 55/90 reads (61%) | called by mutect2, pindel, varscan2
- NEXN | c.1053+2_1053+4delinsAG p.X351_splice | Splice Site (DEL) | VAF 39/116 reads (34%) | called by pindel, varscan2*
- NOS1 | c.3125del p.P1042Lfs*8 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- OR2M2 | c.192_193del p.S64Rfs*47 | Frame Shift Del (DEL) | VAF 143/397 reads (36%) | called by mutect2, pindel*, varscan2*
- PPP2R2D | c.527_528del p.R176Hfs*17 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- SUPT20HL1 | c.2651C>A p.P884H | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TMEM8B | c.1324dup p.R442Pfs*214 | Frame Shift Ins (INS) | VAF 39/121 reads (32%) | called by mutect2, pindel, varscan2
- TTBK1 | c.2803del p.E935Rfs*54 | Frame Shift Del (DEL) | VAF 29/159 reads (18%) | called by mutect2, pindel, varscan2
- ZNF26 | c.1214A>T p.K405M | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACSL4 | c.1941T>A p.A647= (on ENST00000340800 / NM_022977.2; = p.A606= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as COSV100538739; called by muse, mutect2, varscan2
- ADAM33 | c.417G>C p.L139= | Silent (SNP) | VAF 8/170 reads (5%) | catalogued as COSV100597972; called by muse, mutect2
- ARHGAP11A | c.1017A>T p.S339= | Silent (SNP) | VAF 30/37 reads (81%) | catalogued as COSV100853278; called by muse, mutect2
- ARHGAP9 | c.1953G>A p.L651= (on ENST00000393797 / NM_001319850.2; = p.L632= on NM_032496.4) | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1398009587, COSV99954318; called by muse, mutect2, varscan2
- ARL6IP4 | c.972C>T p.P324= (on ENST00000315580 / NM_018694.3; = p.P305= on NM_016638.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV99759255; called by muse, mutect2, varscan2
- BRD9 | c.1365G>T p.T455= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs149025034; called by muse, mutect2
- CARS1 | c.1581C>T p.L527= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV99543081; called by muse, mutect2, varscan2
- CCND1 | c.15C>G p.L5= | Silent (SNP) | VAF 7/143 reads (5%) | catalogued as COSV99919654; called by muse, mutect2
- CRACD | c.2274C>A p.A758= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs1235243717, COSV51728669; called by muse, mutect2, varscan2
- CSF3R | c.1683C>T p.H561= | Silent (SNP) | VAF 88/151 reads (58%) | catalogued as rs771829515, COSV58973445; called by muse, mutect2, varscan2
- DNAH9 | c.9003G>A p.E3001= | Silent (SNP) | VAF 47/54 reads (87%) | catalogued as COSV52339639, COSV99306710; called by muse, mutect2, varscan2
- DPPA3 | c.183C>G p.L61= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100559947, COSV61503060; called by muse, mutect2, varscan2
- DTX3L | c.36C>G p.L12= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV56145079, COSV99950077; called by muse, mutect2, varscan2
- DYSF | c.1863G>T p.G621= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV50337525, COSV99248553; called by muse, mutect2, varscan2
- EBF1 | c.1071G>A p.Q357= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV100565850, COSV100566053; called by muse, mutect2, varscan2
- ESPL1 | c.225G>A p.L75= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99229492; called by muse, mutect2, varscan2
- ESR1 | c.849T>A p.A283= | Silent (SNP) | VAF 124/193 reads (64%) | catalogued as COSV99239913; called by muse, mutect2, varscan2
- F8 | c.6096T>A p.L2032= | Silent (SNP) | VAF 10/232 reads (4%) | catalogued as COSV100811653; called by muse, mutect2
- FAM135B | c.1704C>A p.P568= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV52722356, COSV99425418; called by muse, mutect2, varscan2
- FAM83C | c.1122G>T p.T374= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100981612; called by muse, mutect2, varscan2
- FBXO40 | c.1329G>A p.V443= | Silent (SNP) | VAF 87/132 reads (66%) | catalogued as COSV100573228; called by muse, mutect2, varscan2
- FLG | c.10227A>T p.R3409= | Silent (SNP) | VAF 183/914 reads (20%) | catalogued as COSV100911758; called by muse, mutect2, varscan2
- FLII | c.285A>G p.G95= | Silent (SNP) | VAF 143/314 reads (46%) | catalogued as COSV100493733; called by muse, mutect2, varscan2
- FMR1NB | c.582C>T p.S194= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as COSV100789536; called by muse, mutect2, varscan2
- FNDC3A | c.1170A>G p.Q390= (on ENST00000492622 / NM_001079673.2; = p.Q334= on NM_014923.5) | Silent (SNP) | VAF 59/73 reads (81%) | catalogued as rs369338311; called by muse, mutect2, varscan2
- GIMAP4 | c.336A>G p.P112= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV99750842; called by muse, mutect2, varscan2
- GPR160 | c.861C>T p.L287= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as rs768510633, COSV100576147; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1015C>A p.R339= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100584041; called by muse, mutect2, varscan2
- LAGE3 | c.135G>T p.P45= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100635720; called by muse, mutect2
- LANCL3 | c.1059G>C p.L353= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV101065689; called by muse, mutect2, varscan2
- LRP2 | c.3801C>A p.V1267= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as COSV55548735, COSV99789360; called by muse, mutect2, varscan2
- MAGEB6 | c.1170G>T p.L390= | Silent (SNP) | VAF 88/172 reads (51%) | catalogued as COSV100983786; called by muse, varscan2
- MGAM | c.1572T>C p.D524= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV101527581; called by muse, mutect2, varscan2
- MYB | c.1833A>G p.A611= | Silent (SNP) | VAF 107/185 reads (58%) | catalogued as COSV100214993; called by muse, mutect2, varscan2
- NABP1 | c.531A>G p.P177= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100323064; called by muse, mutect2, varscan2
- NACC1 | c.741A>C p.A247= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99457122; called by muse, mutect2, varscan2
- NEK10 | c.243T>C p.A81= | Silent (SNP) | VAF 28/29 reads (97%) | catalogued as COSV100412062; called by muse, mutect2, varscan2
- NOVA1 | c.561A>C p.I187= | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as COSV99948042; called by muse, mutect2, varscan2
- OSBPL5 | c.1401C>T p.S467= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV99720571; called by muse, mutect2
- PCDHGA5 | c.2280C>A p.T760= | Silent (SNP) | VAF 101/217 reads (47%) | catalogued as COSV99536097, COSV99541763; called by muse, mutect2, varscan2
- PKDREJ | c.4335T>C p.T1445= | Silent (SNP) | VAF 29/36 reads (81%) | catalogued as COSV53546226, COSV99479149; called by muse, mutect2, varscan2
- PNP | c.798A>G p.Q266= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs1240467362, COSV100828991; called by muse, mutect2, varscan2
- PPP1R16B | c.795C>A p.P265= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100239672; called by muse, mutect2, varscan2
- RAD50 | c.1692C>G p.T564= | Silent (SNP) | VAF 49/104 reads (47%) | catalogued as rs876660850, COSV99529190; ClinVar: likely benign; called by muse, mutect2, varscan2
- RASL11B | c.93C>A p.R31= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV99954495; called by muse, mutect2, varscan2
- REG1B | c.57G>C p.L19= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV100521441, COSV59308404; called by muse, mutect2, varscan2
- RIMBP2 | c.1896C>G p.G632= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99899924; called by muse, mutect2, varscan2
- RYR1 | c.2343C>T p.S781= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV100614203, COSV100616225; called by muse, mutect2, varscan2
- SEMA4G | c.225C>T p.A75= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as COSV99272766; called by muse, mutect2, varscan2
- SLC1A6 | c.1527A>G p.V509= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV99693931; called by muse, mutect2, varscan2
- SLC5A2 | c.1332G>A p.V444= | Silent (SNP) | VAF 106/157 reads (68%) | catalogued as COSV100393256; called by muse, mutect2, varscan2
- SNX19 | c.672G>A p.V224= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as COSV99773284; called by muse, mutect2, varscan2
- SNX2 | c.24T>G p.P8= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV101075755; called by muse, varscan2
- STRIP2 | c.1236G>C p.V412= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99973920; called by muse, mutect2, varscan2
- TBX5 | c.1323C>A p.G441= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100091539; called by muse, mutect2, varscan2
- TFAP2B | c.918G>T p.T306= | Silent (SNP) | VAF 73/128 reads (57%) | catalogued as rs898437807, COSV53826675, COSV99540476; called by muse, mutect2, varscan2
- TLR7 | c.2547A>G p.V849= | Silent (SNP) | VAF 68/175 reads (39%) | catalogued as rs773468249, COSV101027960; called by muse, mutect2, varscan2
- TRIP11 | c.3030G>A p.K1010= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1163594474, COSV99970879; called by muse, mutect2, varscan2
- TRPC3 | c.1815T>A p.S605= (on ENST00000379645 / NM_001366479.2; = p.S532= on NM_003305.2) | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV99312994; called by muse, mutect2, varscan2
- TUBB | c.1086G>A p.K362= | Silent (SNP) | VAF 52/123 reads (42%) | catalogued as COSV100013405; called by muse, mutect2, varscan2
- TXNL1 | c.603C>T p.P201= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99469761; called by muse, mutect2, varscan2
- UBXN6 | c.714G>A p.E238= | Silent (SNP) | VAF 38/74 reads (51%) | catalogued as rs776470883, COSV100011324; called by muse, mutect2, varscan2
- ZEB2 | c.675A>T p.S225= | Silent (SNP) | VAF 50/89 reads (56%) | catalogued as COSV100356416, COSV57950483; called by muse, mutect2, varscan2
- ZHX3 | c.1188C>T p.V396= | Silent (SNP) | VAF 56/121 reads (46%) | catalogued as rs147405316; called by muse, mutect2, varscan2
- ZNF69 | c.375A>T p.S125= (on ENST00000429654 / NM_001364730.1; = p.S111= on NM_021915.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/213 reads (48%) | catalogued as COSV100421051; called by muse, mutect2, varscan2
- ZNF709 | c.1632C>T p.S544= | Silent (SNP) | VAF 66/156 reads (42%) | catalogued as COSV101172220; called by muse, mutect2, varscan2
- ADGRL3 | c.3944-1938T>C | Intron (SNP) | VAF 31/67 reads (46%) | catalogued as COSV101541127; called by muse, mutect2, varscan2
- C12orf77 | n.595G>T | RNA (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*3600G>C | 3'UTR (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99951015; called by muse, mutect2, varscan2
- LAIR2 | c.-1C>T | 5'UTR (SNP) | VAF 7/90 reads (8%) | catalogued as COSV100003340, COSV100003437; called by muse, mutect2
- MAPK1IP1L | c.-84G>T | 5'UTR (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100216241; called by muse, mutect2, varscan2
- MIR7-2 | n.65C>A | RNA (SNP) | VAF 8/16 reads (50%) | catalogued as rs756560165; called by muse, varscan2
- OR52A4P | chr11:5121113 G>T | 3'Flank (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- ROS1 | c.228+1736T>C | Intron (SNP) | VAF 17/68 reads (25%) | catalogued as COSV100877319; called by muse, mutect2, varscan2
- RPL31P57 | n.48C>A | RNA (SNP) | VAF 20/41 reads (49%) | catalogued as rs1555643050; called by muse, mutect2, varscan2
